Somatic mutation profile of tumor specimen TCGA-AR-A24L-01A (aliquot TCGA-AR-A24L-01A-11D-A167-09) from TCGA case TCGA-AR-A24L, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 26.6 years (9,706 days).
Specimen TCGA-AR-A24L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b1c09cc-b5d5-4dff-b42e-a0c1848744d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A24L-10A (Blood Derived Normal), aliquot TCGA-AR-A24L-10A-01D-A167-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80d0f412-a793-4fd1-b0d2-511600015ebe

The open-access MAF lists 46 somatic variants for this specimen: 34 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 10, Frame Shift Del 3, Nonstop Mutation 1, Nonsense Mutation 1, Splice Site 1, In Frame Del 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN4 | c.1506G>C p.W502C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53145792, COSV53149705, COSV99400007; called by muse, mutect2
- AHCY | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.118); catalogued as rs377090568; called by muse, mutect2, varscan2
- ALX1 | c.648C>A p.D216E | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.057); catalogued as rs998096551, COSV57492770; called by muse, varscan2
- APOB | c.2778T>G p.I926M | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV51940126; called by muse, mutect2, varscan2
- CCDC78 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV52402823; called by muse, mutect2, varscan2
- CD53 | c.152C>G p.T51R | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54761862; called by muse, mutect2, varscan2
- CD72 | c.707G>C p.G236A | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.864); catalogued as COSV52411455; called by muse, mutect2, varscan2
- CHRNB4 | c.68T>C p.V23A | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55716539; called by muse, mutect2, varscan2
- DCAF6 | c.2581T>A p.*861Kext*1 (on ENST00000312263 / NM_001349778.1; = p.*881Kext*1 on NM_018442.3 and 4 other RefSeq transcripts) | Nonstop Mutation (SNP) | VAF 50/171 reads (29%) | catalogued as COSV56580272; called by muse, mutect2, varscan2
- DCBLD2 | c.835C>A p.H279N | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100471916; called by muse, mutect2
- DISP3 | c.3208G>A p.G1070R | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53829946; called by muse, mutect2, varscan2
- ETV5 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.225); catalogued as rs763950262, COSV60503419; called by muse, mutect2, varscan2
- FGA | c.1443A>C p.E481D | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57397372; called by muse, mutect2
- HP1BP3 | c.959A>G p.K320R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1239881127, COSV100391712; called by muse, varscan2
- LAMP5 | c.524C>G p.P175R | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55716748; called by muse, mutect2, varscan2
- MN1 | c.749C>G p.S250C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.667); catalogued as COSV56559278; called by muse, mutect2, varscan2
- NFKB1 | c.730G>A p.A244T (on ENST00000394820 / NM_001382627.1; = p.A245T on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1164768587, COSV56957669; called by muse, mutect2, varscan2
- NMS | c.61C>T p.Q21* | Nonsense Mutation (SNP) | VAF 52/152 reads (34%) | catalogued as COSV65258830; called by muse, mutect2, varscan2
- PDIA2 | c.792C>G p.S264R | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.158); catalogued as COSV99249600; called by muse, mutect2
- PIWIL4 | c.1302G>C p.W434C | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54410027; called by muse, mutect2, varscan2
- PLEK | c.492G>T p.W164C | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52252459; called by muse, mutect2
- RALGAPB | c.2984C>G p.P995R | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53439314; called by muse, mutect2, varscan2
- TCF4 | c.1567C>G p.L523V | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.899); catalogued as CX114950, COSV61899395; called by muse, mutect2, varscan2
- TNFRSF11B | c.953C>G p.A318G | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as COSV52071846; called by muse, mutect2, varscan2
- TRIM60 | c.467A>G p.E156G | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV61970873; called by muse, mutect2, varscan2
- TTF2 | c.828G>C p.Q276H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV65632905; called by muse, mutect2, varscan2
- UNC13A | c.4526T>C p.I1509T | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV53199011; called by muse, mutect2, varscan2
- ZNF655 | c.1273C>A p.Q425K | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99402050; called by muse, mutect2
- ZNF76 | c.1522G>T p.V508L | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.091); catalogued as COSV57354403; called by muse, mutect2, varscan2
- ARID4B | c.2202_2212del p.E734Dfs*2 | Frame Shift Del (DEL) | VAF 19/107 reads (18%) | called by mutect2, pindel, varscan2
- CADM4 | c.781_788delinsC p.G261Rfs*53 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | called by pindel, varscan2*
- DYNC2H1 | c.10008_10012delinsA p.Y3337Hfs*3 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by pindel, varscan2*
- LMAN2 | c.773_781del p.G258_G260del | In Frame Del (DEL) | VAF 5/33 reads (15%) | called by mutect2, pindel
- PDE1A | c.824+1del p.X275_splice | Splice Site (DEL) | VAF 36/133 reads (27%) | called by mutect2, pindel, varscan2
- CCDC80 | c.1266G>A p.Q422= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV52817728; called by muse, mutect2, varscan2
- CD5L | c.78G>T p.L26= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV63822315; called by mutect2, varscan2
- HAPLN3 | c.354C>T p.R118= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs746694797, COSV62084575; called by muse, mutect2, varscan2
- MED24 | c.2787G>A p.E929= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as rs1340833481, COSV56641236; called by muse, mutect2, varscan2
- OR10S1 | c.204C>A p.L68= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV73342644, COSV73342849, COSV73343087; called by muse, mutect2, varscan2
- PDYN | c.516C>G p.V172= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV54102166; called by muse, mutect2, varscan2
- PKHD1L1 | c.6390C>A p.A2130= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV65745698; called by muse, mutect2, varscan2
- SERPINA12 | c.1206G>C p.V402= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV57943283, COSV57944364; called by muse, mutect2, varscan2
- TBC1D16 | c.72C>A p.G24= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs1229641211, COSV100187915; called by muse, mutect2
- ULK4 | c.1239C>T p.I413= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as COSV57212494; called by muse, mutect2, varscan2
- HERC2P3 | chr15:20453954 C>T | 5'Flank (SNP) | VAF 17/159 reads (11%) | called by muse, mutect2, varscan2
- SSPOP | n.9099C>T | RNA (SNP) | VAF 6/34 reads (18%) | catalogued as rs757425946, COSV100947226, COSV65129534; called by mutect2, varscan2
